Somatic mutation profile of tumor specimen TARGET-30-PASUEA-01A (aliquot TARGET-30-PASUEA-01A-01D) from TARGET case TARGET-30-PASUEA, project TARGET-NBL (Neuroblastoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 2.9 years (1,066 days).
Specimen TARGET-30-PASUEA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4614aca6-a5d4-4d5e-92fc-bda3efc116a9.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PASUEA-10A (Blood Derived Normal), aliquot TARGET-30-PASUEA-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/20b95adf-83cf-4e26-8158-dd92dcb4ef90

The open-access MAF lists 1 somatic variant for this specimen: 1 silent.
By variant classification: Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KMT2A | c.2029C>A p.R677= | Silent (SNP) | VAF 73/220 reads (33%) | catalogued as COSV63289880; called by muse, mutect2, varscan2
